Somatic mutation profile of tumor specimen TCGA-ZP-A9D1-01A (aliquot TCGA-ZP-A9D1-01A-11D-A382-10) from TCGA case TCGA-ZP-A9D1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 56.4 years (20,584 days).
Specimen TCGA-ZP-A9D1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14f68d18-7494-44d8-8344-2843e3b597c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9D1-10B (Blood Derived Normal), aliquot TCGA-ZP-A9D1-10B-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9a22c53-ac0a-48a1-88fa-8e621ee93a61

The open-access MAF lists 147 somatic variants for this specimen: 110 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 35, Nonsense Mutation 4, Splice Site 3, Intron 1, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2A | c.1271C>G p.S424C (on ENST00000219054; = p.S345C on NM_001308169.2) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV99524762; called by muse, mutect2, varscan2
- ADAMTSL5 | c.299T>G p.L100R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV100389024; called by muse, mutect2, varscan2
- ADGRB3 | c.719G>C p.C240S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV100999511, COSV65381041; called by muse, mutect2, varscan2
- ARHGAP36 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99357080; called by muse, mutect2, varscan2
- ARHGEF17 | c.4087G>C p.G1363R | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99734711; called by muse, mutect2, varscan2
- ASCL4 | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as COSV100661129; called by muse, mutect2, varscan2
- ATCAY | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100008375; called by muse, mutect2, varscan2
- ATP8A2 | c.1821A>T p.K607N | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.167); catalogued as COSV99679346; called by muse, mutect2, varscan2
- B3GALT5 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563232; called by muse, mutect2, varscan2
- BCL9 | c.2569T>C p.S857P | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99324252; called by muse, mutect2, varscan2
- BICD1 | c.2752G>T p.V918L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.872); catalogued as COSV99861858; called by muse, mutect2, varscan2
- BPIFB3 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100972270; called by muse, mutect2, varscan2
- BRD8 | c.3239T>C p.L1080S | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV99647604; called by muse, mutect2, varscan2
- CA9 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV100252935; called by muse, mutect2, varscan2
- CACNA1A | c.23T>C p.M8T | Missense Mutation (SNP) | VAF 212/535 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100800274; called by muse, mutect2, varscan2
- CCDC54 | c.656C>A p.T219N | Missense Mutation (SNP) | VAF 122/236 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV99660102; called by muse, mutect2, varscan2
- CCNE2 | c.580T>C p.F194L | Missense Mutation (SNP) | VAF 99/366 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100353569; called by muse, mutect2, varscan2
- CCS | c.428+2T>C p.X143_splice | Splice Site (SNP) | VAF 78/185 reads (42%) | catalogued as COSV100039688; called by muse, mutect2, varscan2
- CDC42BPG | c.2671A>G p.K891E | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs878925562, COSV100711916; called by muse, mutect2, varscan2
- CDH18 | c.1103C>G p.T368S | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV99931248; called by muse, mutect2, varscan2
- CDH19 | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV100050624; called by muse, mutect2, varscan2
- CEP290 | c.86T>A p.L29* | Nonsense Mutation (SNP) | VAF 66/305 reads (22%) | catalogued as COSV99897929; called by muse, mutect2, varscan2
- CNTFR | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100667390; called by muse, mutect2, varscan2
- COBLL1 | c.1671A>C p.E557D (on ENST00000392717; = p.E519D on NM_014900.5) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99527120; called by muse, mutect2, varscan2
- COL6A3 | c.1931T>C p.L644S | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1478389224, COSV99795818; called by muse, mutect2, varscan2
- COP1 | c.2165A>T p.Q722L | Missense Mutation (SNP) | VAF 115/527 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100442508, COSV58171048; called by muse, mutect2, varscan2
- CR2 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889502, COSV65507659; called by muse, mutect2, varscan2
- CRYBB2 | c.475T>A p.Y159N | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236692; called by muse, mutect2
- CTTNBP2 | c.3599T>C p.L1200S | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352699; called by muse, mutect2, varscan2
- CUL1 | c.1375A>G p.K459E | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296318; called by muse, mutect2, varscan2
- CXXC1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV53275585; called by muse, mutect2, varscan2
- DOCK2 | c.2777T>C p.M926T | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99909563; called by muse, mutect2, varscan2
- DYNC2H1 | c.7294T>C p.Y2432H | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100517118; called by muse, mutect2
- EFEMP1 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.406); catalogued as COSV100816678; called by muse, mutect2, varscan2
- ENPP6 | c.877G>T p.V293L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV99698382; called by muse, mutect2, varscan2
- ERRFI1 | c.1236G>T p.R412S | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101087911; called by muse, mutect2, varscan2
- FAM160B1 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.53); catalogued as COSV100985216; called by muse, mutect2, varscan2
- FLG | c.6070C>T p.H2024Y | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs1195638038, COSV100910310; called by muse, mutect2, varscan2
- FNDC1 | c.2578A>G p.R860G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99794589; called by muse, mutect2, varscan2
- FRMPD4 | c.98A>T p.Q33L | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV101041879; called by muse, mutect2, varscan2
- FRY | c.3848T>C p.I1283T | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100968684; called by muse, mutect2, varscan2
- GIMAP6 | c.587A>G p.H196R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100188034; called by muse, mutect2, varscan2
- GRIN2C | c.2305T>A p.W769R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99500456; called by muse, mutect2, varscan2
- GRXCR1 | c.619T>A p.Y207N | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101295580; called by muse, mutect2, varscan2
- HAP1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100169331; called by muse, mutect2, varscan2
- HMGXB4 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99329848; called by muse, mutect2, varscan2
- INPP5D | c.1742A>T p.H581L (on ENST00000445964 / NM_001017915.3; = p.H580L on NM_005541.5) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100856446; called by muse, mutect2, varscan2
- KIDINS220 | c.2503C>A p.R835S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56753061, COSV99874717; called by muse, mutect2, varscan2
- KMT2A | c.10235C>T p.S3412L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100627598; called by muse, mutect2, varscan2
- KMT2D | c.8105A>T p.Q2702L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99976603; called by muse, mutect2, varscan2
- KNDC1 | c.1721C>A p.A574D | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100462959; called by muse, mutect2, varscan2
- KRT77 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100526884; called by muse, mutect2
- LRRC41 | c.1384A>G p.I462V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100586012; called by muse, mutect2, varscan2
- LTBP4 | c.2225G>A p.R742H (on ENST00000308370 / NM_001042544.1; = p.R705H on NM_003573.2) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs544264949, COSV99180297; called by muse, mutect2
- MCM3AP | c.2387A>C p.K796T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV99386334; called by muse, mutect2, varscan2
- MGAM | c.4814C>A p.S1605Y | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101527335, COSV72073448; called by muse, mutect2, varscan2
- MRPL46 | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100428641; called by muse, mutect2, varscan2
- MYBL2 | c.1922A>T p.E641V | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.203); catalogued as COSV99405899; called by muse, mutect2, varscan2
- MYOCD | c.58T>C p.L20= | Splice Region (SNP) | VAF 84/280 reads (30%) | catalogued as COSV100589950; called by muse, mutect2, varscan2
- MYT1L | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs756469250, COSV101218043; called by muse, mutect2, varscan2
- N4BP2 | c.4117A>G p.I1373V | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99788079; called by muse, mutect2, varscan2
- NCOR2 | c.5717C>T p.P1906L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); catalogued as rs1196263716, COSV100656591; called by muse, mutect2, varscan2
- NEB | c.10403A>T p.D3468V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746519954, COSV50825740, COSV99413634; called by muse, mutect2, varscan2
- NEB | c.3449A>T p.K1150M | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99413637; called by muse, mutect2, varscan2
- NINL | c.1044C>A p.F348L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV99624322; called by muse, mutect2, varscan2
- NLRP4 | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs572392165, COSV56714816; called by muse, mutect2, varscan2
- NOX1 | c.46-2A>T p.X16_splice | Splice Site (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99471370; called by muse, mutect2, varscan2
- NRDE2 | c.214A>G p.N72D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1029779123, COSV100583177; called by muse, mutect2, varscan2
- OLFM3 | c.706A>G p.T236A (on ENST00000338858 / NM_001288821.1; = p.T216A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV100128711; called by muse, mutect2, varscan2
- PADI1 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 19/68 reads (28%) | catalogued as COSV100968952; called by muse, mutect2, varscan2
- PCDHB16 | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.144); catalogued as COSV99500715; called by muse, mutect2, varscan2
- PCDHGA7 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99528446; called by muse, mutect2, varscan2
- PCDHGB1 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773771390, COSV99528443; called by muse, mutect2, varscan2
- PDE1C | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs751874343, COSV100370418; called by muse, mutect2, varscan2
- PDHA1 | c.90T>G p.F30L | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100870189; called by muse, mutect2, varscan2
- PFKFB2 | c.1496A>T p.D499V | Missense Mutation (SNP) | VAF 55/219 reads (25%) | PolyPhen benign (0.159); catalogued as COSV100891825; called by muse, mutect2, varscan2
- PGS1 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427923; called by muse, mutect2, varscan2
- PHACTR3 | c.766T>C p.F256L | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs934646941, COSV100732135; called by muse, mutect2, varscan2
- PLCL1 | c.2720C>A p.A907E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101406732; called by muse, varscan2
- PLXNA3 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100859778; called by muse, mutect2, varscan2
- PRDM11 | c.1488G>A p.M496I (on ENST00000530656 / NM_001359633.1; = p.M462I on NM_001256696.1) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99770222; called by muse, mutect2, varscan2
- PRDM9 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 89/286 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV99689572; called by muse, mutect2, varscan2
- PTPRJ | c.377A>G p.K126R | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.242); catalogued as COSV101394217; called by muse, mutect2, varscan2
- PTPRO | c.1136A>G p.E379G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99839340; called by muse, mutect2, varscan2
- PYGO2 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV100868803; called by muse, mutect2, varscan2
- RB1CC1 | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.985); catalogued as rs766400698, COSV99205030; called by muse, mutect2, varscan2
- RGS1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 245/529 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100817369; called by muse, mutect2, varscan2
- RUSC1 | c.736T>C p.W246R | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV99429339; called by muse, mutect2, varscan2
- SFMBT2 | c.796T>A p.S266T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100738252; called by muse, mutect2, varscan2
- SLIT3 | c.41C>G p.A14G | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100264827, COSV60626966; called by muse, mutect2, varscan2
- SLITRK2 | c.1229G>T p.R410M | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157245; called by muse, mutect2, varscan2
- SLITRK2 | c.2507T>A p.L836Q | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100157246; called by muse, mutect2, varscan2
- SORCS3 | c.3005C>A p.S1002Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100863344, COSV63798919; called by muse, mutect2, varscan2
- SYNE2 | c.6545T>C p.L2182S | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100646373; called by muse, mutect2, varscan2
- SYNPO2L | c.1778G>A p.R593H (on ENST00000394810 / NM_001114133.3; = p.R369H on NM_024875.5) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1378102534, COSV100866272; called by muse, mutect2, varscan2
- TADA2B | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.505); catalogued as rs1271238815, COSV100027750; called by muse, mutect2, varscan2
- TCHH | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV100914849, COSV64274174; called by muse, mutect2, varscan2
- TEX35 | c.217-1G>T p.X73_splice | Splice Site (SNP) | VAF 41/162 reads (25%) | catalogued as COSV51106317; called by muse, mutect2, varscan2
- THSD1 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99318639; called by muse, mutect2, varscan2
- TMEM200A | c.1367A>C p.N456T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV99758501; called by muse, varscan2
- TOMM5 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100353520; called by muse, mutect2, varscan2
- TRDN | c.1262A>T p.Q421L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV100520524; called by muse, mutect2, varscan2
- UMODL1 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101248347; called by muse, mutect2, varscan2
- UNC119B | c.557T>G p.F186C | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100763424; called by muse, mutect2
- VPS4A | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99651794; called by muse, mutect2, varscan2
- ZNF229 | c.1195C>A p.H399N | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99349899; called by muse, mutect2, varscan2
- ZNF3 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99447037; called by muse, mutect2, varscan2
- DSG4 | c.2483del p.L828* | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- GFRA2 | c.585C>A p.C195* | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.128T>G p.V43G | Missense Mutation (SNP) | VAF 66/498 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, varscan2
- AK6 | c.195A>G p.L65= | Silent (SNP) | VAF 83/208 reads (40%) | catalogued as COSV101072687; called by muse, mutect2, varscan2
- ARR3 | c.570A>T p.S190= | Silent (SNP) | VAF 111/364 reads (30%) | catalogued as COSV99333446; called by muse, mutect2, varscan2
- BRINP2 | c.99T>A p.A33= | Silent (SNP) | VAF 90/292 reads (31%) | catalogued as COSV100837784; called by muse, mutect2, varscan2
- CACNG4 | c.117C>T p.H39= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as COSV100047243; called by muse, mutect2, varscan2
- CBFA2T2 | c.462A>G p.T154= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as rs750813560, COSV100656076; called by muse, mutect2, varscan2
- CDHR5 | c.610C>T p.L204= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs1564898767, COSV100848508; called by muse, mutect2, varscan2
- CUL1 | c.1374C>T p.D458= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100296316; called by muse, mutect2, varscan2
- CUL4B | c.1269A>G p.E423= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as COSV100340056; called by muse, mutect2, varscan2
- DDX6 | c.360T>A p.S120= | Silent (SNP) | VAF 46/255 reads (18%) | catalogued as COSV99869858; called by muse, mutect2, varscan2
- DTNB | c.552G>A p.G184= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV56484235; called by muse, mutect2, varscan2
- DYNC1H1 | c.600T>C p.I200= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as COSV100794180; called by muse, mutect2, varscan2
- FMN2 | c.4992C>A p.I1664= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100142035; called by muse, mutect2, varscan2
- HTR3C | c.669C>A p.A223= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV100570454; called by muse, mutect2, varscan2
- KIF14 | c.3324T>C p.Y1108= | Silent (SNP) | VAF 54/290 reads (19%) | catalogued as COSV100950551; called by muse, mutect2, varscan2
- KRT27 | c.738C>T p.N246= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs1397928127, COSV100053139; called by muse, mutect2, varscan2
- LAMA1 | c.8076A>C p.P2692= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV101054565; called by muse, mutect2, varscan2
- LCE2D | c.54C>A p.P18= | Silent (SNP) | VAF 58/261 reads (22%) | catalogued as COSV100909507, COSV64228907; called by muse, mutect2, varscan2
- LHX1 | c.924A>G p.P308= | Silent (SNP) | VAF 50/234 reads (21%) | called by muse, mutect2, varscan2
- LRIF1 | c.1020C>A p.I340= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100870777, COSV63898097; called by muse, mutect2, varscan2
- MDN1 | c.9087A>G p.P3029= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101020660; called by muse, mutect2, varscan2
- MUC5B | c.8274C>G p.S2758= | Silent (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- OLR1 | c.741A>G p.Q247= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100376262; called by muse, mutect2, varscan2
- PDE3A | c.1413A>G p.A471= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as rs1417109973, COSV100761508; called by muse, mutect2
- PRF1 | c.1641A>C p.P547= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100942495; called by muse, mutect2, varscan2
- PROCA1 | c.699C>T p.I233= (on ENST00000439862 / NM_001366301.1; = p.I205= on NM_152465.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99972464; called by muse, mutect2, varscan2
- PRPF19 | c.408A>G p.P136= | Silent (SNP) | VAF 23/154 reads (15%) | catalogued as COSV99920406; called by muse, mutect2, varscan2
- SALL3 | c.3699C>T p.I1233= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV101609903; called by muse, mutect2, varscan2
- SREBF2 | c.2067C>T p.S689= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs200493376, COSV63333311; called by muse, mutect2, varscan2
- SYNGAP1 | c.3675C>A p.S1225= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as COSV99537677; called by muse, mutect2, varscan2
- TPR | c.1146A>G p.A382= | Silent (SNP) | VAF 62/553 reads (11%) | catalogued as COSV100823535; called by muse, mutect2, varscan2
- TTBK1 | c.1041T>A p.P347= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV99443446; called by muse, mutect2, varscan2
- UNC13C | c.789A>G p.L263= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs1310361049, COSV99509971; called by muse, mutect2, varscan2
- WDR19 | c.435A>G p.G145= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV99975068; called by muse, mutect2, varscan2
- ZNF506 | c.504T>A p.T168= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV101475599; called by muse, mutect2, varscan2
- ZP4 | c.1203T>A p.P401= | Silent (SNP) | VAF 124/260 reads (48%) | catalogued as COSV100850481; called by muse, mutect2, varscan2
- GSPT1 | c.-30T>C | 5'UTR (SNP) | VAF 34/120 reads (28%) | catalogued as COSV101341683; called by muse, mutect2, varscan2
- PLPP4 | c.57-227G>C | Intron (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100956106; called by muse, mutect2, varscan2
